Somatic mutation profile of tumor specimen TCGA-G3-A3CI-01A (aliquot TCGA-G3-A3CI-01A-11D-A20W-10) from TCGA case TCGA-G3-A3CI, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 71.8 years (26,224 days).
Specimen TCGA-G3-A3CI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c8d4e37-8124-4c86-b9cc-cda779a94898.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A3CI-10A (Blood Derived Normal), aliquot TCGA-G3-A3CI-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0904444b-84ea-4e88-b919-414e780c09e3

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY4 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1247592927, COSV53474614; called by muse, mutect2, varscan2
- APOB | c.2114T>C p.F705S | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51928809; called by muse, mutect2, varscan2
- ARL5B | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV66011036; called by muse, mutect2, varscan2
- CR1 | c.5310A>C p.E1770D | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65456951; called by muse, mutect2, varscan2
- CYP17A1 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64004765, COSV64004817; called by muse, mutect2, varscan2
- NCEH1 | c.268C>T p.H90Y (on ENST00000538775; = p.H58Y on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as rs762841949, COSV56433540; called by muse, mutect2, varscan2
- NEB | c.11560G>C p.D3854H | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50881854, COSV51436297; called by muse, mutect2
- NUP214 | c.3400A>G p.T1134A | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776088512, COSV63908390; called by muse, mutect2, varscan2
- SMOC1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as COSV62760101; called by muse, mutect2, varscan2
- TRPM2 | c.2989A>T p.S997C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55967588; called by muse, mutect2, varscan2
- USP29 | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as rs771763319, COSV54237978; called by muse, mutect2, varscan2
- MYMK | c.291G>A p.V97= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- OR1E2 | c.747T>A p.T249= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV50265473; called by muse, mutect2, varscan2
- PLPP3 | c.537C>T p.Y179= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV64838947; called by muse, mutect2, varscan2
- SLC22A12 | c.1137C>T p.F379= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as CM151767, COSV60571396; called by muse, mutect2, varscan2
- SLIT3 | c.1491C>T p.S497= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs187066924; called by muse, mutect2, varscan2
